Gene-level copy-number profile of tumor specimen HCM-SANG-0299-C15-01A-01D-A80T-32 from HCMI case HCM-SANG-0299-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0299-C15-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e0a1b7f8-22fb-404d-9818-253818975690.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0299-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,750 have no estimate.
https://portal.gdc.cancer.gov/files/8261ebcf-9562-4c39-a989-fabc22eb0fe1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 348; copy number 1: 28,052; copy number 2: 26,364; copy number 3: 2,618; copy number 4: 732; copy number 5: 154; copy number 6: 193; copy number 7: 46; copy number 8: 74; copy number 9: 170; copy number 10: 1; copy number 11: 5; copy number 12: 19; copy number 15: 2; copy number 16: 3; copy number 18: 1; copy number 22: 26; copy number 30: 1; copy number 55: 4; copy number 56: 1; copy number 62: 47; copy number 76: 12.

Homozygous deletions (total copy number 0; autosomes only): 321 genes in 98 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:47,761,132–47,820,237, 2 genes (within-gene range 0–1): AL691459.1, AC096541.1.
- chr1:54,641,754–54,742,308, 2 genes (within-gene range 0–1): MROH7, MROH7-TTC4.
- chr1:75,122,518–75,133,058, 2 genes (within-gene range 0–1): AC099786.3, AC099786.1.
- chr1:98,045,242–98,046,171, 2 genes (within-gene range 0–1): MIR2682, MIR137.
- chr1:110,150,494–110,202,202, 3 genes: SLC6A17, SLC6A17-AS1, AL355990.1.
- chr3:10,324,023–10,708,007, 5 genes (within-gene range 0–1): ATP2B2, MIR378B, MIR885, ATP2B2-IT1, ATP2B2-IT2.
- chr3:29,797,652–29,934,156, 2 genes (within-gene range 0–1): MTND4LP9, RBMS3-AS1.
- chr4:69,931,068–70,002,570, 3 genes: CSN1S1, CSN2, STATH.
- chr10:274,190–744,958, 8 genes: DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1.
- chr10:933,026–1,019,932, 3 genes (within-gene range 0–1): AL359878.2, AL359878.1, GTPBP4.
- chr10:1,049,538–1,737,525, 7 genes: WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1.
- chr10:5,594,984–6,353,827, 28 genes: LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1, GDI2, NRBF2P5, AL596094.1, ANKRD16, RPL12P28, FBH1, AL137186.2, IL15RA, IL2RA, AL137186.3, AL137186.1, RPL32P23, RBM17, PFKFB3, RN7SKP78, MIR3155A, MIR3155B, AL157395.1, Y_RNA, LINC02649, SDCBPP1, LINC02656.
- chr10:12,195,965–14,462,142, 46 genes (within-gene range 0–1): CDC123, AL512770.1, RN7SL198P, CAMK1D, AL391314.1, RNU6ATAC39P, AL731559.1, MIR4480, MIR4481, MIR548Q, AL353586.1, CCDC3, RNA5SP300, RPL5P25, OPTN, SNRPGP5, AL355355.2, AL355355.1, BTBD7P1, RPL36AP36, MCM10, RNU6-6P, UCMA, PHYH, RBISP1, SEPHS1, AL355870.1, BEND7, Y_RNA, AL590677.1, PRPF18, RPL6P24, AL157392.5, AL157392.3, FRMD4A, AL157392.4, AL157392.1, RNA5SP301, AL157392.2, NUTF2P5, AC044781.1, AL157896.1, AL139405.1, MIR4293, Metazoa_SRP, MIR1265.
- chr10:14,986,942–15,021,863, 4 genes (within-gene range 0–1): OR7E110P, OR7E26P, OR7E115P, DCLRE1CP1.
- chr11:1,991,096–2,001,470, 5 genes: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr11:22,010,402–22,170,001, 2 genes: AC116534.1, AC107882.1.
- chr11:28,986,635–29,266,734, 2 genes (within-gene range 0–1): OR2BH1P, AC090791.1.
- chr11:29,594,326–29,982,392, 6 genes: LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616.
- chr11:44,719,392–44,932,423, 2 genes (within-gene range 0–1): TSPAN18-AS1, TSPAN18.
- chr11:45,387,215–45,542,487, 5 genes (within-gene range 0–1): AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:84,720,826–84,890,961, 3 genes (within-gene range 0–1): AP001825.1, AP001825.2, AP001825.3.
- chr11:84,997,226–85,021,655, 2 genes (within-gene range 0–1): AP000857.1, HNRNPCP6.
- chr12:2,603,350–2,691,200, 4 genes (within-gene range 0–1): CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1.
- chr12:2,740,064–2,775,658, 3 genes (within-gene range 0–1): LINC02371, IQSEC3P1, AC092471.1.
- chr12:5,948,877–6,238,271, 5 genes: VWF, RN7SL69P, AC005845.1, CD9, Y_RNA.
- chr12:72,610,678–73,143,858, 2 genes (within-gene range 0–2): CHCHD3P2, AC090503.2.
- chr13:18,609,132–18,935,554, 18 genes (within-gene range 0–1): LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408.
- chr14:22,701,476–22,887,678, 12 genes: AL160314.2, OR6E1P, AL160314.3, AL135998.1, OXA1L, SLC7A7, MRPL52, MMP14, Y_RNA, Y_RNA, LRP10, REM2.
- chr14:25,820,366–25,998,805, 2 genes: AL359396.2, AL132633.1.
- chr15:73,870,949–73,889,214, 2 genes: AC018943.1, TBC1D21.
- chr16:5,084,284–5,235,822, 4 genes (within-gene range 0–1): EEF2KMT, AC026458.2, AC074051.3, ENPP7P14.
- chr16:11,359,845–11,527,245, 3 genes (within-gene range 0–1): AC099489.1, AC099489.2, AC099489.3.
- chr16:12,545,482–12,557,694, 2 genes (within-gene range 0–1): AC131391.1, AC010333.1.
- chr16:48,637,143–49,350,504, 11 genes (within-gene range 0–1): AC023813.3, AC023813.4, KLF8P1, RNU6-257P, AC023827.1, MTND4LP25, AC044798.3, AC044798.1, AC044798.2, CBLN1, AC007614.1.
- chr16:49,373,804–49,924,154, 12 genes: C16orf78, AC007861.1, AC007861.2, LINC02179, ZNF423, ADAM3B, MRPS21P7, AC027348.2, MRPS21P8, AC027348.1, AC007603.2, AC007603.1.
- chr21:42,950,928–43,168,646, 7 genes (within-gene range 0–1): MIR5692B, AP001630.1, PKNOX1, CBS, U2AF1, AP001631.2, MRPL51P2.
- chr22:32,507,820–33,058,381, 6 genes: SYN3, SYN3-AS1, RNA5SP497, Z73495.1, TIMP3, Z83846.1.
- chr22:33,320,865–33,436,669, 2 genes (within-gene range 0–1): Z82173.1, MIR4764.
- chr22:34,756,676–35,425,431, 13 genes: LINC02885, ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, HMOX1, MCM5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 759 genes in 48 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–522,928, 31 genes, copy number 5: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:587,629–594,768, 1 gene, copy number 5 (within-gene range 3–5): AC114498.1.
- chr1:800,879–1,442,882, 68 genes, copy number 6–16 (within-gene range 4–16) (broad region; genes not listed).
- chr1:2,013,213–3,438,621, 40 genes, copy number 5 (within-gene range 4–5): AL391845.2, GABRD, AL391845.1, PRKCZ, AL590822.2, PRKCZ-AS1, FAAP20, AL590822.1, SKI, AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2, RER1, PEX10, PLCH2, AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1, AL592464.2, AL592464.3, AL592464.1, ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1.
- chr1:3,306,636–3,775,982, 17 genes, copy number 5: AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2, TP73-AS1, AL136528.1, CCDC27, SMIM1.
- chr1:240,489,573–240,612,155, 1 gene, copy number 5 (within-gene range 2–5): GREM2.
- chr1:240,549,867–240,590,748, 2 genes, copy number 5: AL358176.2, AL358176.4.
- chr2:89,252,211–89,310,144, 8 genes, copy number 5: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.
- chr2:196,133,583–196,176,503, 2 genes, copy number 6: STK17B, AC114760.2.
- chr2:203,315,390–203,447,728, 3 genes, copy number 5 (within-gene range 3–5): MRPL50P2, ABI2, AC080075.1.
- chr4:932,387–1,026,898, 5 genes, copy number 7: TMEM175, DGKQ, SLC26A1, IDUA, FGFRL1.
- chr5:32,522,758–42,191,523, 148 genes, copy number 7–12 (broad region; genes not listed).
- chr7:1,459,937–1,589,626, 8 genes, copy number 6: AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1.
- chr7:16,646,131–16,719,898, 2 genes, copy number 5: BZW2, AC073333.1.
- chr8:125,648,327–129,683,770, 48 genes, copy number 56–62 (within-gene range 2–62): AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr8:143,412,749–143,430,732, 3 genes, copy number 5: AC105118.1, MAFA-AS1, MAFA.
- chr8:143,553,207–143,633,756, 11 genes, copy number 5: GSDMD, MROH6, AC067930.4, NAPRT, AC067930.5, AC067930.1, EEF1D, TIGD5, PYCR3, GFUS, AC067930.2.
- chr8:143,915,153–143,976,734, 2 genes, copy number 8: PLEC, MIR661.
- chr8:144,400,086–144,529,132, 21 genes, copy number 6: MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1, AC084125.1, KIFC2, FOXH1, PPP1R16A, AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82.
- chr9:136,546,173–136,687,457, 7 genes, copy number 6: MIR4674, NALT1, LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2.
- chr9:136,969,243–137,302,271, 45 genes, copy number 6: LINC02692, PTGDS, AL807752.7, LCNL1, PAXX, CLIC3, ABCA2, C9orf139, FUT7, AL807752.6, NPDC1, ENTPD2, AL807752.4, AL807752.2, SAPCD2, AL807752.3, UAP1L1, MAN1B1-DT, MAN1B1, SNORD62, DPP7, GRIN1, LRRC26, AL929554.1, MIR3621, TMEM210, ANAPC2, SSNA1, TPRN, TMEM203, NDOR1, RNF208, CYSRT1, RNF224, SLC34A3, TUBB4B, FAM166A, STPG3-AS1, STPG3, NELFB, TOR4A, BX255925.2, BX255925.1, BX255925.4, NRARP.
- chr9:137,423,350–137,441,816, 2 genes, copy number 7: NOXA1, ENTPD8.
- chr11:777,578–915,058, 17 genes, copy number 5–6: AP006621.3, AP006621.5, AP006621.2, CEND1, SLC25A22, AP006621.6, PIDD1, RPLP2, SNORA52, PNPLA2, AP006621.1, CRACR2B, CD151, POLR2L, TSPAN4, AP006623.1, CHID1.
- chr11:1,074,875–1,110,511, 1 gene, copy number 6: MUC2.
- chr11:1,947,278–1,989,920, 2 genes, copy number 6–18: MRPL23, MRPL23-AS1.
- chr12:22,609,228–24,562,544, 9 genes, copy number 6–8 (within-gene range 1–12): AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5.
- chr12:24,212,421–28,978,685, 97 genes, copy number 8–76 (broad region; genes not listed).
- chr14:105,140,982–105,181,323, 4 genes, copy number 7: JAG2, MIR6765, AL512356.1, NUDT14.
- chr14:105,472,962–105,499,575, 4 genes, copy number 9: CRIP2, CRIP1, AL928654.3, TEDC1.
- chr14:105,583,731–105,588,395, 1 gene, copy number 8: IGHA2.
- chr16:560,394–800,737, 34 genes, copy number 6: PRR35, PIGQ, NHLRC4, Z98883.1, RAB40C, WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1, METRN, ANTKMT, CCDC78, HAGHL, CIAO3, MSLN, AL031258.1, MSLNL, MIR662, RPUSD1, CHTF18, GNG13.
- chr16:975,761–1,230,184, 17 genes, copy number 7–8 (within-gene range 2–8): CEROX1, SOX8, AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1, AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10, TPSB2.
- chr16:1,333,638–1,351,878, 2 genes, copy number 8: BAIAP3, TSR3.
- chr16:88,803,789–88,856,970, 3 genes, copy number 5 (within-gene range 4–5): CDT1, APRT, GALNS.
- chr19:925,781–1,279,244, 25 genes, copy number 5–15: ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2, STK11, HMGB2P1, CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr20:62,307,955–62,551,526, 13 genes, copy number 5–6 (within-gene range 3–6): LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1.
- chr20:63,235,883–63,240,495, 2 genes, copy number 5: BIRC7, MIR3196.
- chr20:63,293,186–63,574,239, 15 genes, copy number 6–16: COL20A1, RNU6-994P, CHRNA4, AL121827.1, KCNQ2, AL353658.1, KCNQ2-AS1, EEF1A2, AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2.
- chr21:7,744,962–8,454,792, 26 genes, copy number 22: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr21:13,038,160–13,120,807, 4 genes, copy number 7–11 (within-gene range 7–12): ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 25,229. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
